CCDI case PBCMTU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/40b2ce71-345f-4b66-837c-6534c2e2029a

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Biospecimens (3 samples)
- Sample 0DVKDM: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVKDX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DVKEF: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
